Somatic mutation profile of tumor specimen TCGA-WB-A80V-01A (aliquot TCGA-WB-A80V-01A-12D-A35I-08) from TCGA case TCGA-WB-A80V, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 63.7 years (23,254 days).
Specimen TCGA-WB-A80V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26e85c0f-7fad-4de1-98af-e08d99986807.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WB-A80V-10A (Blood Derived Normal), aliquot TCGA-WB-A80V-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/acd89c14-75ca-42e7-9eb0-085efa0379e3

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 13, Silent 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RET | c.2753T>C p.M918T | Missense Mutation (SNP) | VAF 53/135 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs74799832, CM941246, COSV60685905; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ALDH1A3 | c.1003G>A p.V335M | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as rs923605749, COSV60901592; called by muse, mutect2, varscan2
- ANKRD17 | c.2857A>G p.I953V | Missense Mutation (SNP) | VAF 40/67 reads (60%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs746461793; called by muse, mutect2, varscan2
- CYP4A11 | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 14/18 reads (78%) | catalogued as rs754705570; called by muse, mutect2, varscan2
- RNF149 | c.1088C>T p.S363F | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); catalogued as COSV99766769; called by muse, mutect2
- SSH1 | c.1285A>G p.I429V | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.123); catalogued as rs144199955; called by muse, mutect2, varscan2
- ADAT1 | c.475T>A p.C159S | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ARL6IP4 | c.1088C>T p.A363V (on ENST00000315580 / NM_018694.3; = p.A344V on NM_016638.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.316); called by muse, mutect2
- PLCH1 | c.3076T>A p.S1026T (on ENST00000340059 / NM_001130960.2; = p.S1018T on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/42 reads (83%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SEH1L | c.588G>T p.K196N | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- SIGLEC11 | c.1553T>C p.L518P | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TM7SF3 | c.1211A>G p.D404G | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- TTLL6 | c.2360C>T p.S787F (on ENST00000393382 / NM_001130918.3; = p.S480F on NM_173623.3) | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- ZNF503 | c.1640G>A p.G547E | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LPA | c.4344T>C p.C1448= | Silent (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2, varscan2
- TGFBRAP1 | c.648A>T p.I216= | Silent (SNP) | VAF 8/185 reads (4%) | called by muse, mutect2
- TRIM71 | c.2166C>T p.H722= | Silent (SNP) | VAF 12/17 reads (71%) | called by muse, mutect2, varscan2
